Somatic mutation profile of tumor specimen TCGA-XU-A92Q-01A (aliquot TCGA-XU-A92Q-01A-11D-A423-09) from TCGA case TCGA-XU-A92Q, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 50.1 years (18,281 days).
Specimen TCGA-XU-A92Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b42ee94d-367d-4b87-a394-1b941e514fa4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A92Q-10A (Blood Derived Normal), aliquot TCGA-XU-A92Q-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/609388b6-1fc6-45de-9f60-0cbb0cd3b42f

The open-access MAF lists 25 somatic variants for this specimen: 22 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 135/380 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- ACTR2 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs757353258, COSV53199530; called by muse, mutect2, varscan2
- AHCYL2 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.368); catalogued as rs745705126, COSV100273077; called by muse, mutect2, varscan2
- CLPTM1 | c.1831G>A p.V611M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs199735762; called by muse, mutect2, varscan2
- LIG3 | c.1271C>T p.S424L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs143109771, COSV52008223; called by muse, mutect2, varscan2
- LRSAM1 | c.719A>G p.D240G | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs775659934; called by muse, mutect2, varscan2
- NOL6 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs369599517; called by muse, mutect2, varscan2
- BVES | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- CAPN6 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHGA | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, varscan2
- CNTRL | c.2963A>T p.K988M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM83D | c.671T>C p.I224T | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- HRAS | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- KIF13A | c.5020G>T p.A1674S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.24); called by muse, mutect2
- MECOM | c.86T>C p.M29T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.39814T>C p.Y13272H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- OR8G2P | c.322G>C p.A108P | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- PVRIG | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- SURF4 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.68292A>T p.E22764D (on ENST00000591111; = p.E15340D on NM_003319.4) | Missense Mutation (SNP) | VAF 24/37 reads (65%) | PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- UTP20 | c.7810G>A p.E2604K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF462 | c.4492del p.V1498* | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- KCNMB4 | c.108C>G p.G36= | Silent (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.489C>A p.S163= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- MIR9-1 | n.15A>G | RNA (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
